TCGA case TCGA-4V-A9QS — Thymoma (TCGA-THYM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Thymic Epithelial Neoplasms; Primary site: Thymus; Tissue source site: Hospital Louis Pradel. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/88c0af76-b1ba-478f-a42b-8a50c0568d5e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: France; Age at index: 53 years; Vital status: Alive.

Diagnoses (2)
1. Thymoma, type B2, malignant (the primary disease): ICD-O-3 morphology code: 8584/3; ICD-10 code: C37; Tissue or organ of origin: Thymus; Site of resection or biopsy: Thymus; Classification of tumor: primary; Age at diagnosis: 53.2 years (19,443 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; Masaoka stage: Stage IVa; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 774 days (2.1 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 54 days; Days to treatment end: 104 days; Treatment dose: 60 Gy; Treatment outcome: Complete Response; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS.
2. Recurrence of diagnosis 1 (Thymoma, type B2, malignant), site: Pleura, NOS. Age at diagnosis: 55.3 years (20,195 days); Days to diagnosis: 752 days (2.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (4 entries)
- Days to follow up: 596 days (1.6 years); Disease response: Tumor Free.
- Days to follow up: 601 days (1.6 years); Disease response: Tumor Free.
- Day 752 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Pleura, NOS; Days to recurrence: 752 days (2.1 years).
- Days to follow up: 774 days (2.1 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 65 kg; Height: 161 cm; BMI: 25.1.
- Timepoint category: Prior to Diagnosis; Comorbidities: Myasthenia Gravis; Myasthenia gravis classification: Class V; Risk factors: Myasthenia Gravis.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-4V-A9QS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 140 mg.
  Slide TCGA-4V-A9QS-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-4V-A9QS-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-4V-A9QS-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Stage record: Masaoka stage: IVa.
- Primary pathology, Histological type list: Histologic diagnosis: Thymoma, Type B2.
- Primary pathology: Method initial path diagnosis: Median Sternectomy; History myasthenia gravis: Yes.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 774 days; disease-specific survival: no event (censored), 774 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 752 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-4V-A9QS-01A-11D-A422-01): tumor purity 0.18, ploidy 2.54, whole-genome doublings 0.
